CCDI case PBBHZD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8483c96b-2548-48a2-b59b-df2f4f20b0bf

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 4.9 years (1,785 days).

Biospecimens (3 samples)
- Sample 0D9W5K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9W5T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9W5U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
